Somatic mutation profile of tumor specimen MP2PRT-PAWBBC-TMP1-A (aliquot MP2PRT-PAWBBC-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAWBBC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,389 days).
Specimen MP2PRT-PAWBBC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d35276a-c544-4fd2-b226-1a5bc18eeb4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWBBC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWBBC-NB1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e32ced75-238a-4fe8-b2d6-a7a77d4dd731

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPK3 | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 52/556 reads (9%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs1172324544, COSV51936070; called by muse, mutect2
- CCDC144A | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 156/424 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.05); catalogued as COSV61402412, COSV61402991; called by muse, varscan2
- CDK16 | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 24/492 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1344085582; called by muse, mutect2
- DHTKD1 | c.907G>A p.G303S | Missense Mutation (SNP) | VAF 65/456 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.269); catalogued as rs748174586, COSV99536781; called by muse, mutect2, varscan2
- GRIN2B | c.3898C>T p.R1300W | Missense Mutation (SNP) | VAF 182/444 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1565453201, COSV74206505; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 53/383 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TANC2 | c.3449G>A p.R1150H | Missense Mutation (SNP) | VAF 71/424 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as rs377115331; called by muse, mutect2, varscan2
- CTCF | c.1202A>G p.H401R | Missense Mutation (SNP) | VAF 15/292 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- FAM227A | c.398C>A p.A133E | Missense Mutation (SNP) | VAF 35/366 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- IRAG2 | c.2768A>G p.E923G | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2
- SBF1 | c.288_289insAGGTAGA p.V98* | Nonsense Mutation (INS) | VAF 84/227 reads (37%) | called by mutect2, pindel*, varscan2
- SPI1 | c.471_485delinsGCTGGGCTCCC p.G158Lfs*27 | Frame Shift Del (DEL) | VAF 80/674 reads (12%) | called by pindel, varscan2*
- CYP1A2 | c.300G>A p.R100= | Silent (SNP) | VAF 67/467 reads (14%) | catalogued as rs137918189; called by muse, mutect2, varscan2
- MSLN | c.1383C>T p.P461= (on ENST00000382862 / NM_013404.4; = p.P453= on NM_005823.6) | Silent (SNP) | VAF 47/349 reads (13%) | called by muse, mutect2, varscan2
